Surgical pathology report (de-identified scan), TCGA case TCGA-CG-4444, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Indivumed, specimen TCGA-CG-4444-01A (Primary Tumor).

■
Diagnosis/diagnoses:

1.: Gastrectomy preparation with tumor-free resection margins and with the inclusion of a subendocardial, ulcerated poorly differentiated adenocarcinoma or gastric carcinoma at least partially of the diffuse type (so-called signet-ring carcinoma) situated in the region of the lesser curvature with infiltration of the subserosa and with multiple regional lymph node metastases. ■ pT2b pN2 15/37 ■

Source: NCI Genomic Data Commons file c9a19a50-6c65-4e6a-8c1d-d5a3b0b522e6 (TCGA-CG-4444.43742CFE-E2AA-4918-B8B1-92B4234E9EE0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).